Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3OA, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3OA-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:
MRN:
DOB:
Gender:
HCN:
Ordering MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

For Malignancy History		X

Specimen(s) Received

1. Parathyroid: Right Lower
2. right hemi- thyroidectomy - stitch marks upper pole right lobe

Diagnosis

1. No pathological diagnosis: Parathyroid (right lower) biopsy.
2. Papillary carcinoma, follicular variant with focal trabecular growth and oncocytic change 2.2 cm, right; mild chronic lymphocytic thyroiditis with atrophic changes: Thyroid, right hemithyroidectomy specimen.

Comment

2. This case has been seen in consultation with Dr. and he agrees with the interpretation and diagnosis.

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:

4.9 cm
2.2 cm
1.2 cm
Isthmus +/- pyramidal lobe:
1.5 cm
0.5 cm
0.2 cm

Specimen Weight: 8.5 g
Tumor Focality: Unifocal

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.2cm
Additional dimension: 1.7 cm
Additional dimension: 1.2 cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Other architecture: trabecular
Classical cytomorphology
Oncocytic or oxyphilic cytomorphology

1CD-0-3
carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS C73.9

2/5/12

[page 2 of 2]
Surgical Pathology Consultation Report

Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "RT Lower Parathyroid" contains a piece of tan-white tissue that measures 0.2 x 0.2 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

2. The specimen labeled with the patient's name and as "Right Hemithyroidectomy Stitch Marks Upper Pole RT Lobe", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 8.5 g. The lobe measures 4.9 cm SI x 2.2 cm ML x 1.2 cm AP and the isthmus measures 1.5 SI x 0.5 cm ML x 0.2 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands and/or no lymph nodes are identified grossly. The upper lobe contains a well delineated nodule(s) that measure 2.2 cm SI x 1.7 cm ML x 1.2 cm AP. The remainder of the thyroid tissue is unremarkable grossly. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted in toto.

2A-I lobe, superior to inferior

2J isthmus

Quick Section Diagnosis

1. Right lower parathyroid, qs: - Parathyroid tissue identified

MD

Source: NCI Genomic Data Commons file dab8f7af-9d67-4d1b-a6ff-17b887a41bcf (TCGA-EM-A3OA.68C1C276-EB58-4A3C-8693-0A7229214A28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).